Somatic mutation profile of tumor specimen TCGA-EJ-5516-01A (aliquot TCGA-EJ-5516-01A-01D-1576-08) from TCGA case TCGA-EJ-5516, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 49.2 years (17,980 days).
Specimen TCGA-EJ-5516-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2727b0ac-3309-4bdd-a8ef-577959d3f5d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-5516-10A (Blood Derived Normal), aliquot TCGA-EJ-5516-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1c732f8-d971-488d-a8a6-f62707055961

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 4, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD1E | c.521G>T p.R174L | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV63770616, COSV63772837; called by muse, mutect2, varscan2
- CSTB | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.664); catalogued as COSV52367065; called by muse, mutect2, varscan2
- EEF2K | c.1612C>T p.R538C | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753635343, COSV53783886; called by muse, mutect2
- EXOSC4 | c.590C>A p.A197E | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.746); catalogued as COSV60156058; called by muse, mutect2, varscan2
- KCNK9 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as rs756601239, COSV57279846; called by muse, mutect2, varscan2
- KDM3A | c.2143C>T p.H715Y | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57222636; called by muse, mutect2, varscan2
- KIF3B | c.1007G>A p.R336H | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770420525, COSV65227069; called by muse, mutect2, varscan2
- MRGPRX4 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58590961; called by muse, mutect2, varscan2
- MYH8 | c.2018T>C p.V673A | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67967826; called by muse, mutect2, varscan2
- SPRR3 | c.269G>T p.C90F | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT tolerated (0.7); PolyPhen benign (0.089); catalogued as COSV54880195, COSV54881420; called by muse, varscan2
- SYNE1 | c.22262C>T p.P7421L (on ENST00000367255 / NM_182961.4; = p.P7350L on NM_033071.3) | Missense Mutation (SNP) | VAF 16/329 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55024062; called by muse, mutect2
- THBS1 | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52953510; called by muse, mutect2
- TIMELESS | c.3374A>G p.H1125R | Missense Mutation (SNP) | VAF 95/693 reads (14%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.042); catalogued as rs1271032697, COSV57512877; called by muse, mutect2, varscan2
- VPS13D | c.2488C>T p.R830* | Nonsense Mutation (SNP) | VAF 5/82 reads (6%) | catalogued as rs1375929155, COSV50651063; called by muse, mutect2
- VSIG4 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.799); catalogued as COSV66074146; called by muse, mutect2
- CPT1B | c.2055C>T p.S685= | Silent (SNP) | VAF 11/142 reads (8%) | catalogued as rs1195638578, COSV56417498; called by muse, mutect2
- GRIA2 | c.1557C>T p.L519= | Silent (SNP) | VAF 85/531 reads (16%) | catalogued as COSV52395909; called by muse, mutect2, varscan2
- PPIP5K1 | c.4092C>T p.T1364= (on ENST00000396923; = p.T1339= on NM_014659.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 10/248 reads (4%) | catalogued as COSV55810319; called by muse, mutect2
- UEVLD | c.645C>G p.L215= | Silent (SNP) | VAF 10/188 reads (5%) | catalogued as COSV57875506; called by muse, mutect2
- SND1 | c.1779+6756C>A | Intron (SNP) | VAF 85/513 reads (17%) | catalogued as rs767457793, COSV100689508; called by muse, mutect2, varscan2
